Somatic mutation profile of tumor specimen TARGET-20-PARFXF-09A (aliquot TARGET-20-PARFXF-09A-01D) from TARGET case TARGET-20-PARFXF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.0 years (7,685 days).
Specimen TARGET-20-PARFXF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e9d001f-5b69-410d-bff1-a66fc309eb17.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARFXF-14A (Bone Marrow Normal), aliquot TARGET-20-PARFXF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b799a91a-7f4e-42a8-8814-e0b7dc630724

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1102delinsGG p.R368Gfs*5 | Frame Shift Ins (INS) | VAF 57/128 reads (45%) | catalogued as COSV60066146, COSV60066729, COSV60067470, COSV60068404, COSV60071219, COSV60075554, COSV60080690, COSV60085668; called by pindel, varscan2*
- WT1 | c.1094_1096del p.T365_L366delinsI | In Frame Del (DEL) | VAF 18/87 reads (21%) | called by pindel*, varscan2
